Somatic mutation profile of tumor specimen BA2322D (aliquot aq-BA2322D) from BEATAML1.0 case 2060, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.4 years (12,948 days).
Specimen BA2322D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0feb5b4-4bd3-41f2-8952-d3db8af13c9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2565D (Solid Tissue Normal), aliquot aq-BA2565D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cae6f1b9-fa19-42dd-832d-8d227993d3f3

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HHATL | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768201980; called by mutect2, varscan2
- PCDHGB6 | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1012868761; called by muse, mutect2
- STK3 | c.1169G>T p.R390I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1176079716; called by muse, mutect2
- AARS2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- GMEB1 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.112); called by muse, mutect2
- PCDHA5 | c.2115G>A p.A705= | Silent (SNP) | VAF 22/218 reads (10%) | called by muse, mutect2, varscan2
- TM2D1 | c.9C>T p.A3= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- ZNF837 | c.798G>A p.P266= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs769645216; called by muse, mutect2
- POTEC | c.1126+1516G>C | Intron (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
